CCDI case PBCMYP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/68c0789d-5bd3-447c-9dac-288957ac621e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,089 days).

Biospecimens (2 samples)
- Sample 0DW8H1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DW8HA: Tissue type: Tumor; Specimen type: Solid Tissue.
